Somatic mutation profile of tumor specimen MMRF_1597_1_BM_CD138pos (aliquot MMRF_1597_1_BM_CD138pos_T2_KHS5U_K14087) from MMRF case MMRF_1597, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 54.0 years (19,706 days).
Specimen MMRF_1597_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38493385-d88a-441b-b199-e8d55000963b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1597_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1597_1_PB_Whole_C1_KHS5U_K14077; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4954b1b3-94b6-47f9-aeac-802912a7f568

The open-access MAF lists 157 somatic variants for this specimen: 65 protein-altering or splice-affecting, 21 silent, 71 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, 3'UTR 38, Intron 22, Silent 21, 3'Flank 6, Nonsense Mutation 5, 5'UTR 4, Frame Shift Del 4, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.13267C>G p.P4423A | Missense Mutation (SNP) | VAF 42/332 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV68943355; called by muse, mutect2, varscan2
- ACTA1 | c.248A>G p.D83G | Missense Mutation (SNP) | VAF 4/100 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.379); catalogued as COSV64203768; called by muse, mutect2
- ASH2L | c.1837C>G p.H613D | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.977); catalogued as rs1240229535, COSV99166993; called by muse, mutect2
- AVPR1A | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.075); catalogued as COSV54547949; called by muse, mutect2, varscan2
- BMP2K | c.821G>T p.C274F | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV58598905; called by muse, mutect2, varscan2
- BPIFB4 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as rs143050216; called by muse, mutect2, varscan2
- C10orf71 | c.691G>C p.G231R | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs183879740, COSV100110414, COSV60505553; called by muse, mutect2, varscan2
- CCT8L2 | c.1266G>A p.M422I | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs757335583; called by muse, mutect2, varscan2
- CLIP4 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as rs185134118; called by muse, mutect2, varscan2
- DAGLA | c.2650G>A p.G884S | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs778135090, COSV57198343; called by muse, mutect2
- DIAPH1 | c.1826C>T p.P609L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs764883573; called by muse, mutect2, varscan2
- DLD | c.535A>G p.I179V | Missense Mutation (SNP) | VAF 44/189 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.442); catalogued as rs1200484911; called by muse, mutect2, varscan2
- DOCK5 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs143551268, COSV52398678; called by muse, mutect2, varscan2
- EPHA7 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs889062730, COSV65170562; called by muse, mutect2
- GABRD | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs896016478; called by muse, mutect2
- IGHV2-70 | c.89T>C p.L30P | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs549341348; called by muse, varscan2
- IGHV2-70D | c.305C>G p.T102R | Missense Mutation (SNP) | VAF 33/46 reads (72%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs1310540287; called by muse, varscan2
- IL6ST | c.1213C>G p.L405V | Missense Mutation (SNP) | VAF 65/459 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs781572746, COSV61143322; called by muse, mutect2, varscan2
- IRF6 | c.974G>T p.G325V | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM022402, CM133872; called by muse, mutect2, varscan2
- KDM4F | c.622A>T p.T208S | Missense Mutation (SNP) | VAF 6/131 reads (5%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.964); catalogued as rs570057318; called by muse, mutect2
- LRRC66 | c.782G>A p.S261N | Missense Mutation (SNP) | VAF 121/281 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.049); catalogued as rs751045603; called by muse, mutect2, varscan2
- NKD1 | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.672); catalogued as rs774978613; called by muse, mutect2, varscan2
- PCDHB1 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs1384862222, COSV100128433; called by muse, mutect2
- RAB10 | c.320T>C p.I107T | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1242606679; called by muse, mutect2, varscan2
- SF3B3 | c.2077T>A p.Y693N | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV56788800; called by muse, mutect2, varscan2
- SIGLEC7 | c.910C>G p.L304V | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as COSV58315281; called by muse, mutect2, varscan2
- SLC18A3 | c.886G>C p.G296R | Missense Mutation (SNP) | VAF 8/240 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60322230; called by muse, mutect2
- SMAD6 | c.1366G>A p.D456N | Missense Mutation (SNP) | VAF 56/317 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as rs779579065; called by muse, varscan2
- TAMALIN | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201792271; called by muse, mutect2, varscan2
- TENM4 | c.538C>A p.P180T | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.999); catalogued as rs1250513590, COSV53635662; called by muse, mutect2, varscan2
- ASH2L | c.1700C>A p.S567* | Nonsense Mutation (SNP) | VAF 9/111 reads (8%) | called by muse, mutect2
- CACNA1H | c.7034C>A p.P2345Q | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CACNA2D1 | c.2070A>C p.K690N (on ENST00000356253 / NM_001366867.1; = p.K678N on NM_000722.4) | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC168 | c.17704C>T p.Q5902* | Nonsense Mutation (SNP) | VAF 18/87 reads (21%) | called by muse, mutect2, varscan2
- CD2BP2 | c.781G>T p.E261* | Nonsense Mutation (SNP) | VAF 28/165 reads (17%) | called by muse, mutect2, varscan2
- CPED1 | c.1034C>A p.S345Y | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2
- CYLD | c.588del p.F196Lfs*7 | Frame Shift Del (DEL) | VAF 41/129 reads (32%) | called by mutect2, pindel, varscan2
- DNAH9 | c.833C>A p.A278D | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- ENDOD1 | c.1364T>G p.I455S | Missense Mutation (SNP) | VAF 11/269 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- FLNC | c.6619G>A p.V2207M | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GINM1 | c.923C>T p.T308I | Missense Mutation (SNP) | VAF 84/198 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- IGHV2-70D | c.172A>G p.I58V | Missense Mutation (SNP) | VAF 49/98 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, varscan2
- IGHV2-70D | c.107C>G p.T36S | Missense Mutation (SNP) | VAF 40/58 reads (69%) | SIFT tolerated (0.1); PolyPhen benign (0.332); called by muse, varscan2
- IGHV2-70D | c.75G>C p.E25D | Missense Mutation (SNP) | VAF 34/42 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- IGLV3-1 | c.160_176del p.Y54Pfs*11 | Frame Shift Del (DEL) | VAF 44/44 reads (100%) | called by mutect2, pindel*, varscan2*
- IGLV3-22 | c.337A>G p.N113D | Missense Mutation (SNP) | VAF 80/134 reads (60%) | SIFT tolerated (0.64); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MEFV | c.1355T>A p.L452Q | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, varscan2
- MUC17 | c.9311G>T p.S3104I | Missense Mutation (SNP) | VAF 20/378 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- PAX2 | c.287T>C p.V96A | Missense Mutation (SNP) | VAF 96/198 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PDLIM4 | c.386G>A p.G129D | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT tolerated (0.62); PolyPhen benign (0.036); called by muse, mutect2
- PGAP1 | c.1473C>A p.Y491* | Nonsense Mutation (SNP) | VAF 8/65 reads (12%) | called by muse, mutect2, varscan2
- PHLPP1 | c.3190G>T p.E1064* | Nonsense Mutation (SNP) | VAF 24/47 reads (51%) | called by muse, mutect2, varscan2
- PRKD3 | c.287A>C p.K96T | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- RABEPK | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- RFLNA | c.295C>T p.P99S (on ENST00000546355 / NM_001365156.1; = p.P18S on NM_181709.4) | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC18A3 | c.887G>C p.G296A | Missense Mutation (SNP) | VAF 9/243 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); called by muse, mutect2
- SYCP2L | c.2283T>A p.N761K | Missense Mutation (SNP) | VAF 80/183 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TENT5C | c.164T>A p.V55D | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TENT5C | c.358del p.L120Cfs*5 | Frame Shift Del (DEL) | VAF 13/63 reads (21%) | called by mutect2, pindel, varscan2
- TENT5C | c.836del p.P279Rfs*30 | Frame Shift Del (DEL) | VAF 25/69 reads (36%) | called by mutect2, pindel, varscan2
- THBD | c.1575C>A p.S525R | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- TMEM229A | c.269C>T p.S90L | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.27); called by muse, mutect2
- XKR8 | c.889A>T p.I297F | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- ZNF200 | c.409C>G p.Q137E | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF217 | c.206T>G p.F69C | Missense Mutation (SNP) | VAF 79/184 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCB5 | c.2634T>C p.T878= (on ENST00000404938 / NM_001163941.2; = p.T433= on NM_178559.6) | Silent (SNP) | VAF 13/40 reads (33%) | called by mutect2, varscan2
- CAPN6 | c.1219C>T p.L407= | Silent (SNP) | VAF 14/124 reads (11%) | called by mutect2, varscan2
- CELSR3 | c.1725C>T p.D575= | Silent (SNP) | VAF 12/242 reads (5%) | called by muse, mutect2
- CNTLN | c.510T>C p.D170= | Silent (SNP) | VAF 9/71 reads (13%) | called by muse, mutect2, varscan2
- IGF2BP2 | c.927A>T p.T309= | Silent (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- IGLV3-22 | c.96C>G p.S32= | Silent (SNP) | VAF 70/114 reads (61%) | catalogued as rs540053412; called by muse, mutect2, varscan2
- ITPRIPL2 | c.141C>T p.G47= | Silent (SNP) | VAF 8/143 reads (6%) | called by muse, mutect2
- KCTD19 | c.2040C>T p.P680= | Silent (SNP) | VAF 17/40 reads (43%) | called by muse, mutect2, varscan2
- MORN1 | c.258C>T p.F86= | Silent (SNP) | VAF 41/109 reads (38%) | called by muse, mutect2, varscan2
- MRGPRG | c.327C>T p.F109= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV60040098; called by muse, mutect2, varscan2
- MTTP | c.1950C>A p.I650= | Silent (SNP) | VAF 12/84 reads (14%) | called by muse, mutect2, varscan2
- MYH13 | c.2652C>A p.L884= | Silent (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- OR52K1 | c.630G>C p.V210= | Silent (SNP) | VAF 14/109 reads (13%) | catalogued as COSV56903510; called by muse, mutect2, varscan2
- OR5M8 | c.639A>T p.I213= | Silent (SNP) | VAF 44/315 reads (14%) | called by muse, mutect2, varscan2
- PCDHA12 | c.27G>A p.P9= | Silent (SNP) | VAF 39/188 reads (21%) | catalogued as rs782342111; called by muse, mutect2, varscan2
- PGM2L1 | c.762G>A p.S254= | Silent (SNP) | VAF 12/241 reads (5%) | catalogued as rs1433185026, COSV53346885; called by muse, mutect2
- RAI1 | c.4938G>T p.G1646= | Silent (SNP) | VAF 20/248 reads (8%) | called by muse, mutect2
- SLC45A1 | c.303C>T p.Y101= | Silent (SNP) | VAF 14/137 reads (10%) | catalogued as rs769137840, COSV57095723; called by muse, mutect2
- TAF1L | c.864G>T p.L288= | Silent (SNP) | VAF 44/222 reads (20%) | called by muse, mutect2, varscan2
- TENM2 | c.5028G>A p.E1676= (on ENST00000518659 / NM_001122679.2; = p.E1437= on NM_001080428.3) | Silent (SNP) | VAF 15/104 reads (14%) | called by muse, mutect2, varscan2
- TNFSF9 | c.402G>T p.V134= | Silent (SNP) | VAF 12/148 reads (8%) | called by muse, mutect2
- AC027088.1 | n.240G>C | RNA (SNP) | VAF 9/141 reads (6%) | called by muse, mutect2
- ADAMTSL3 | c.*729G>A | 3'UTR (SNP) | VAF 75/109 reads (69%) | catalogued as rs769569225; called by muse, mutect2, varscan2
- AGBL4 | c.1267+2663G>A | Intron (SNP) | VAF 28/121 reads (23%) | called by muse, mutect2, varscan2
- ALDH9A1 | c.*687C>A | 3'UTR (SNP) | VAF 18/90 reads (20%) | called by muse, mutect2, varscan2
- AP1S1 | c.*270G>T | 3'UTR (SNP) | VAF 31/189 reads (16%) | called by muse, mutect2, varscan2
- ARL15 | c.*1743G>T | 3'UTR (SNP) | VAF 13/99 reads (13%) | called by muse, mutect2, varscan2
- ASH2L | c.1720-24C>G | Intron (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- ASH2L | c.*109C>T | 3'UTR (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- BAG4 | c.*1597G>C | 3'UTR (SNP) | VAF 18/219 reads (8%) | called by muse, mutect2
- BAG4 | c.*2279G>T | 3'UTR (SNP) | VAF 14/193 reads (7%) | called by muse, mutect2
- BAG4 | c.*2523G>A | 3'UTR (SNP) | VAF 4/57 reads (7%) | called by muse, mutect2
- C8orf37 | c.*1087A>C | 3'UTR (SNP) | VAF 22/56 reads (39%) | called by muse, mutect2, varscan2
- C9 | c.*233C>T | 3'UTR (SNP) | VAF 9/80 reads (11%) | catalogued as rs769157827, COSV99662720; called by muse, mutect2, varscan2
- CDH4 | c.170-24952C>A | Intron (SNP) | VAF 12/222 reads (5%) | called by muse, mutect2
- CEP120 | c.1039-57C>G | Intron (SNP) | VAF 26/105 reads (25%) | called by muse, mutect2, varscan2
- CPSF4 | c.103+2302C>G | Intron (SNP) | VAF 9/129 reads (7%) | called by muse, mutect2
- DGKI | chr7:137390156 C>A | 3'Flank (SNP) | VAF 21/37 reads (57%) | called by muse, mutect2, varscan2
- DYNC1LI1 | c.*655G>A | 3'UTR (SNP) | VAF 20/82 reads (24%) | called by muse, mutect2, varscan2
- EFCAB14 | c.-701C>T | 5'UTR (SNP) | VAF 9/54 reads (17%) | catalogued as rs1406765433; called by muse, mutect2, varscan2
- FAM172A | c.*2445C>T | 3'UTR (SNP) | VAF 4/50 reads (8%) | catalogued as rs1010311130; called by muse, mutect2
- FOXR1 | c.-147G>A | 5'UTR (SNP) | VAF 27/186 reads (15%) | called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.2114+1670A>C | Intron (SNP) | VAF 17/25 reads (68%) | called by muse, mutect2, varscan2
- G6PD | chrX:154531428 del GGAGGGGT | 3'Flank (DEL) | VAF 23/60 reads (38%) | called by mutect2, pindel, varscan2
- GPR158 | c.*2112G>A | 3'UTR (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2, varscan2
- GSKIP | c.*867A>C | 3'UTR (SNP) | VAF 25/76 reads (33%) | called by muse, mutect2, varscan2
- HTT | c.1867+31G>T | Intron (SNP) | VAF 8/132 reads (6%) | called by muse, mutect2
- INAVA | c.*212G>A | 3'UTR (SNP) | VAF 17/433 reads (4%) | catalogued as COSV100949863; called by muse, mutect2
- IRF6 | c.*1694C>T | 3'UTR (SNP) | VAF 18/57 reads (32%) | catalogued as rs778941285; called by muse, mutect2, varscan2
- L1CAM | c.*697G>A | 3'UTR (SNP) | VAF 16/105 reads (15%) | called by muse, mutect2, varscan2
- LSS | c.*38+835C>A | Intron (SNP) | VAF 56/121 reads (46%) | called by muse, mutect2, varscan2
- MAPK1IP1L | c.*1269del | 3'UTR (DEL) | VAF 10/80 reads (13%) | called by mutect2, pindel, varscan2
- MEF2C | c.-139-340A>G | Intron (SNP) | VAF 7/50 reads (14%) | called by muse, mutect2, varscan2
- MGAM | c.4619-13782C>T | Intron (SNP) | VAF 44/232 reads (19%) | called by muse, mutect2, varscan2
- MLST8 | c.*141C>G | 3'UTR (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2, varscan2
- NECTIN1 | c.*3134T>C | 3'UTR (SNP) | VAF 22/119 reads (18%) | called by muse, mutect2, varscan2
- NOL9 | c.*3325C>T | 3'UTR (SNP) | VAF 21/110 reads (19%) | catalogued as rs1473601917; called by muse, mutect2, varscan2
- NRF1 | chr7:129756038 G>A | 3'Flank (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- OR51E2 | c.*810A>T | 3'UTR (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2
- PCDH11X | c.*1888C>T | 3'UTR (SNP) | VAF 11/228 reads (5%) | called by muse, mutect2
- PHF3 | c.*937C>T | 3'UTR (SNP) | VAF 6/65 reads (9%) | called by muse, mutect2
- PID1 | chr2:229024947 ins G | 3'Flank (INS) | VAF 11/38 reads (29%) | called by mutect2, pindel*, varscan2*
- PLEKHH3 | c.2205+10A>G | Intron (SNP) | VAF 62/153 reads (41%) | called by muse, mutect2, varscan2
- RBM34 | c.*145T>G | 3'UTR (SNP) | VAF 27/146 reads (18%) | called by muse, mutect2, varscan2
- SATB2 | c.*166C>A | 3'UTR (SNP) | VAF 26/63 reads (41%) | called by muse, mutect2, varscan2
- SDHA | c.*277C>T | 3'UTR (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- SLC1A2 | c.*567T>A | 3'UTR (SNP) | VAF 11/64 reads (17%) | called by muse, mutect2, varscan2
- SLC36A4 | c.*1195C>G | 3'UTR (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- SLITRK2 | c.*414A>T | 3'UTR (SNP) | VAF 15/48 reads (31%) | called by muse, mutect2, varscan2
- SNAP47 | c.1249-4364A>G | Intron (SNP) | VAF 10/86 reads (12%) | called by muse, mutect2, varscan2
- SPANXN1 | c.*217C>A | 3'UTR (SNP) | VAF 16/120 reads (13%) | called by muse, mutect2, varscan2
- SPEF2 | c.2839+1664C>T | Intron (SNP) | VAF 13/88 reads (15%) | called by muse, mutect2, varscan2
- SRSF4 | c.*518A>C | 3'UTR (SNP) | VAF 16/85 reads (19%) | called by muse, mutect2, varscan2
- SYDE1 | c.431-85C>T | Intron (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- SYTL2 | c.1459+2013C>G | Intron (SNP) | VAF 13/147 reads (9%) | catalogued as rs1291013888; called by muse, mutect2
- SYTL5 | c.*342T>A | 3'UTR (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- TECRL | chr4:64276853 A>T | 3'Flank (SNP) | VAF 10/37 reads (27%) | called by muse, mutect2, varscan2
- TET2 | c.*369A>T | 3'UTR (SNP) | VAF 22/34 reads (65%) | called by muse, mutect2, varscan2
- TMED7 | c.-190G>A | 5'UTR (SNP) | VAF 70/198 reads (35%) | called by muse, mutect2, varscan2
- TMTC1 | c.*5958A>T | 3'UTR (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- TNS1 | chr2:217799740 C>A | 3'Flank (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- TPO | c.482+2873G>A | Intron (SNP) | VAF 16/128 reads (13%) | called by muse, mutect2
- TSC22D4 | c.*35C>T | 3'UTR (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- TUBGCP2 | c.1215-785T>C | Intron (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2, varscan2
- TUSC1 | c.-21G>A | 5'UTR (SNP) | VAF 12/23 reads (52%) | called by muse, mutect2, varscan2
- UHRF1 | c.-10-1314T>G | Intron (SNP) | VAF 34/107 reads (32%) | called by muse, mutect2, varscan2
- VPS36 | c.990+141C>A | Intron (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2
- VPS54 | c.379-2813G>A | Intron (SNP) | VAF 8/50 reads (16%) | catalogued as rs1376756195; called by muse, varscan2
- ZNF462 | c.*1944G>A | 3'UTR (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- ZNF493 | c.-132+11312T>C | Intron (SNP) | VAF 38/58 reads (66%) | called by muse, varscan2
- ZNF684 | c.239-1697A>C | Intron (SNP) | VAF 16/58 reads (28%) | called by muse, mutect2, varscan2
- ZNF776 | c.*2551T>C | 3'UTR (SNP) | VAF 12/105 reads (11%) | called by muse, mutect2, varscan2
